Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-A8B5, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-A8B5-TTP1-C (Primary Tumor).

Previous exams

Previous exams exist.

Material description

1. Upper lobe, left lung
2. Lymph node N. 5
3. Lymph node N.11
4. Lymph node N.12

Macro description

1. 16 x 8 x 5 cm pulmonary lobe. When you cut, the parenchyma, shows greyish-blackish neoformation, hard compactness, soft margins, bigger axis of 4,5 cm, that appears infiltrate the above pleura. Free the remaining parenchyma. From hilum we close off 3 lymph nodes.
2. Four fragments of anthracotic tissue, biggest of 1.8 cm
3. Fragment of anthracotic tissue, bigger axis of 0.5 cm
4. Fragment of anthracotic tissue, bigger axis of 1 cm

Micro description

1.2.3.4. Poorly differentiated adenocarcinoma, acinar type. The neoplasm is made up of acinar complex structures, sometimes with cribose appearance, supported by rich fibrous thick stroma. Cytologically the neoplastic elements are cubic-cylindrical, with vesicular nucleus, nucleolus from unapparent to clear, cytoplasm relatively large eosinophil finely vacuolated. There are mitoses (about 10 mitoses/10 HPF). We observe blood vessel intratumoral invasion with thrombosis of lumen of some vessels. The neoplasm approaches the visceral pleura without infiltrating the serosa. In the pulmonary parenchyma, surrounding the neoplasm, we observe endoalveolar macrophages with pigment smoke related. The bronchial margin, closed off from the surgical slice, is negative for neoplasm. Lymph nodes: we observe metastasis of adenocarcinoma in 2 peribronchial lymph nodes isolated from the surgical sample and in the lymph node n. 5 (sample n. 2). All other lymph nodes examined show reactive, not specific, modifications.

Conclusion and Histopatological Diagnosis

1. Poorly differentiated adenocarcinoma, acinar type. Metastases in 2 peribronchial lymph nodes. Bronchial margin negative for neoplasm
2. Lymph nodes metastasis of adenocarcinoma 3.4. Reactive lymph nodes, negative for metastasis.

Staging pTNM: MISSING

ICD-0-3

adenocarcinoma, acinar 8550/3

Site: (L) lung, upper lobe C34.1

ICD-10

C34.12

hw
2/12/16

Reviewer Initials	BT #	Date Reviewed 2/12/16

Source: NCI Genomic Data Commons file 45ce4325-99ae-43bc-9460-3b96a5507d5d (CDDP-A8B5-TTP1.8E3A940C-DCEA-46DA-BDAD-45EBA427C7E3.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).